Somatic mutation profile of tumor specimen C3N-02585-01 (aliquot CPT0183750008) from CPTAC case C3N-02585, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.2 years (23,804 days).
Specimen C3N-02585-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4d1d5b4-e3fa-4396-8a7d-7f3b38a73058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02585-71 (Blood Derived Normal), aliquot CPT0183810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b77f734-1ba0-4538-9d21-073cb1eaf43e

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Frame Shift Ins 6, Frame Shift Del 3, Intron 3, Nonsense Mutation 3, Splice Site 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 256/1083 reads (24%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 108/600 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-2A>T p.X33_splice | Splice Site (SNP) | VAF 117/461 reads (25%) | hotspot (GDC flag); catalogued as COSV52678373, COSV52848662, COSV53375861, COSV53887648; called by muse, mutect2, varscan2
- ACAD10 | c.1197_1198del p.H399Qfs*10 | Frame Shift Del (DEL) | VAF 34/246 reads (14%) | catalogued as rs774510931; called by pindel, varscan2
- BRWD3 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1380960013, COSV64743418, COSV64754310; called by muse, mutect2, varscan2
- COLEC12 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs148602317; called by muse, mutect2, varscan2
- DCBLD2 | c.1496A>G p.N499S | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs377415899; called by muse, mutect2, varscan2
- DDHD2 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs1220182181; called by muse, mutect2, varscan2
- FAM83H | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 185/1032 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs1554621855; called by muse, mutect2, varscan2
- FRMPD4 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as rs760858730, COSV101043886; called by muse, mutect2, varscan2
- GJD2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 113/838 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs1481161920; called by mutect2, varscan2
- IGLL1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 94/754 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.044); catalogued as rs747083240, COSV50770134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 63/415 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV56441625; called by muse, mutect2, varscan2
- MARK2 | c.1644dup p.T549Hfs*4 (on ENST00000402010 / NM_001039469.2; = p.T515Hfs*4 on NM_017490.4) | Frame Shift Ins (INS) | VAF 40/378 reads (11%) | catalogued as rs1275438822; called by mutect2, pindel
- MUC5B | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs745336157; called by muse, mutect2
- NXF1 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 65/388 reads (17%) | catalogued as rs1242043093, COSV53677747; called by muse, mutect2, varscan2
- PCDHB6 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 261/1470 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50718471; called by muse, varscan2
- PRX | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1289022588; called by muse, varscan2
- SDS | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs541907463; called by muse, mutect2, varscan2
- SMAD4 | c.454+2T>A p.X152_splice | Splice Site (SNP) | VAF 61/334 reads (18%) | catalogued as COSV61687223; called by muse, mutect2, varscan2
- SYNE1 | c.13552C>T p.R4518C (on ENST00000367255 / NM_182961.4; = p.R4447C on NM_033071.3) | Missense Mutation (SNP) | VAF 92/500 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569216024, COSV54916166; called by muse, mutect2, varscan2
- THSD1 | c.2249G>C p.G750A | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV99318973; called by muse, mutect2, varscan2
- TRUB1 | c.545T>C p.I182T | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs572364497; called by muse, mutect2, varscan2
- ADAMTS17 | c.2510_2559del p.L837Pfs*25 | Frame Shift Del (DEL) | VAF 76/1008 reads (8%) | called by mutect2, pindel
- AHNAK2 | c.8083G>A p.D2695N | Missense Mutation (SNP) | VAF 36/740 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2
- ANK3 | c.9509A>G p.E3170G | Missense Mutation (SNP) | VAF 95/573 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARID1A | c.1113dup p.Q372Afs*28 | Frame Shift Ins (INS) | VAF 35/161 reads (22%) | called by mutect2, pindel, varscan2
- BBX | c.2088dup p.F697Ifs*8 | Frame Shift Ins (INS) | VAF 83/568 reads (15%) | called by mutect2, varscan2
- HERC2 | c.8152G>T p.G2718* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- LTC4S | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 146/729 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- OR51C1P | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCSK5 | c.4989A>T p.G1663= | Splice Region (SNP) | VAF 56/229 reads (24%) | called by muse, varscan2
- PRPF31 | c.102T>A p.D34E | Missense Mutation (SNP) | VAF 111/594 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RB1CC1 | c.3148G>T p.V1050F | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SAMD9L | c.3474dup p.A1159Sfs*13 | Frame Shift Ins (INS) | VAF 80/488 reads (16%) | called by mutect2, pindel, varscan2
- SLC23A2 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STAB2 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TTC21A | c.2975dup p.L992Ffs*5 | Frame Shift Ins (INS) | VAF 28/164 reads (17%) | called by mutect2, pindel
- ZNF483 | c.1312dup p.T438Nfs*3 | Frame Shift Ins (INS) | VAF 70/427 reads (16%) | called by mutect2, pindel, varscan2
- ZNF684 | c.299del p.L100* | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- CTBP1 | c.330C>T p.A110= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as rs199545251; called by muse, mutect2, varscan2
- CYP21A2 | c.507C>T p.T169= | Silent (SNP) | VAF 278/1173 reads (24%) | called by muse, mutect2, varscan2
- FMR1NB | c.108G>A p.S36= | Silent (SNP) | VAF 61/341 reads (18%) | catalogued as rs151160499, COSV65070991; called by muse, mutect2, varscan2
- JAKMIP1 | c.366C>T p.D122= | Silent (SNP) | VAF 97/533 reads (18%) | catalogued as rs199613129; called by muse, mutect2, varscan2
- MUC16 | c.39768C>T p.Y13256= | Silent (SNP) | VAF 67/367 reads (18%) | called by muse, mutect2, varscan2
- OR51A7 | c.381C>T p.H127= | Silent (SNP) | VAF 69/331 reads (21%) | catalogued as COSV100834593; called by muse, mutect2, varscan2
- PC | c.1374C>T p.N458= | Silent (SNP) | VAF 129/650 reads (20%) | called by muse, mutect2, varscan2
- RNF213 | c.7176G>A p.T2392= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs774601132, COSV60398008; called by muse, mutect2
- SLC35E2B | c.636G>T p.L212= | Silent (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- TRIM71 | c.282C>T p.C94= | Silent (SNP) | VAF 148/772 reads (19%) | called by muse, varscan2
- TSPAN16 | c.249C>T p.S83= | Silent (SNP) | VAF 49/422 reads (12%) | called by muse, mutect2, varscan2
- ZBTB2 | c.90C>T p.I30= | Silent (SNP) | VAF 29/404 reads (7%) | called by muse, mutect2
- ZSWIM8 | c.768C>T p.D256= | Silent (SNP) | VAF 71/449 reads (16%) | catalogued as rs753132557, COSV101290168; called by muse, mutect2, varscan2
- ADAM23 | c.2360-4083C>T | Intron (SNP) | VAF 56/351 reads (16%) | catalogued as rs995523709; called by muse, mutect2, varscan2
- CHCHD7 | c.-17+1019A>G | Intron (SNP) | VAF 36/204 reads (18%) | catalogued as COSV57616594; called by muse, mutect2, varscan2
- SERPING1 | c.*7C>T | 3'UTR (SNP) | VAF 54/291 reads (19%) | called by muse, mutect2, varscan2
- SHANK2 | c.1108-11294C>T | Intron (SNP) | VAF 87/511 reads (17%) | catalogued as rs781914901, COSV58344310; called by muse, mutect2, varscan2
